Gene-level copy-number profile of specimen HCM-BROD-0020-C15-85A from HCMI case HCM-BROD-0020-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 67.6 years (24,696 days).
Specimen HCM-BROD-0020-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file baed8ad7-42fb-4783-a3e6-bf1d811ce23b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0020-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/67c11976-7b71-4e4b-b099-687b2fe02820

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 724; copy number 2: 22,410; copy number 3: 26,236; copy number 4: 6,338; copy number 5: 1,359; copy number 6: 1,032; copy number 7: 175; copy number 8: 152; copy number 9: 116; copy number 10: 17; copy number 11: 95; copy number 12: 24; copy number 13: 22; copy number 14: 22; copy number 16: 4; copy number 17: 6; copy number 19: 58; copy number 20: 5; copy number 31: 19; copy number 37: 56; copy number 63: 10; copy number 82: 4.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 785 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,026,895–42,452,051, 56 genes, copy number 7–20: UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1.
- chr6:54,846,771–57,646,850, 28 genes, copy number 8: FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1.
- chr8:2,033,508–2,165,552, 4 genes, copy number 17: AC245164.1, MYOM2, MIR7160, AC245164.2.
- chr8:9,555,144–12,704,056, 109 genes, copy number 7–19 (broad region; genes not listed).
- chr8:115,408,496–118,622,112, 24 genes, copy number 8–13 (within-gene range 3–15): TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1.
- chr8:122,977,026–134,979,279, 196 genes, copy number 8–16 (broad region; genes not listed).
- chr9:136,006,537–137,423,211, 108 genes, copy number 8 (broad region; genes not listed).
- chr9:137,877,782–138,253,217, 7 genes, copy number 8 (within-gene range 5–8): CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr15:20,901,441–20,901,609, 1 gene, copy number 7: ZNF519P2.
- chr15:20,960,675–20,961,581, 1 gene, copy number 8: OR11J2P.
- chr15:21,293,653–21,325,241, 3 genes, copy number 8 (within-gene range 6–8): AC068446.1, AC068446.2, RNU6-1235P.
- chr15:96,438,570–101,850,324, 123 genes, copy number 7–8 (broad region; genes not listed).
- chr17:38,419,280–39,747,291, 65 genes, copy number 9–63 (broad region; genes not listed).
- chr17:41,212,706–41,977,740, 56 genes, copy number 37 (within-gene range 3–37): KRTAP9-12P, KRTAP9-2, KRTAP9-3, KRTAP9-8, KRTAP9-4, KRTAP9-9, KRTAP9-6, KRTAP9-11P, KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1, KRTAP17-1, TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2, TTC25, CNP.
- chr17:44,793,199–44,850,476, 4 genes, copy number 82 (within-gene range 3–82): AC005180.2, AC005180.1, GJC1, HIGD1B.

Autosomal genes at a single copy (total copy number 1): 724. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
